Somatic mutation profile of tumor specimen TARGET-20-PASUMD-09A (aliquot TARGET-20-PASUMD-09A-01D) from TARGET case TARGET-20-PASUMD, project TARGET-AML (Acute Myeloid Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Acute myeloid leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 3.6 years (1,307 days).
Specimen TARGET-20-PASUMD-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7fd6b34a-57e8-4410-be69-e2a4c2276547.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-20-PASUMD-14A (Bone Marrow Normal), aliquot TARGET-20-PASUMD-14A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/edcecc99-81fa-42d3-967d-7475fa1b639a

The open-access MAF lists 4 somatic variants for this specimen: 4 protein-altering or splice-affecting.
By variant classification: Frame Shift Ins 2, In Frame Del 1, Missense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EZH2 | c.2172dup p.D725* (on ENST00000460911 / NM_001203247.2; = p.D730* on NM_004456.5) | Frame Shift Ins (INS) | VAF 37/211 reads (18%) | catalogued as rs797045568; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- FLT3 | c.2508_2510del p.I836del | In Frame Del (DEL) | VAF 57/297 reads (19%) | catalogued as rs121913490; ClinVar: likely pathogenic; called by mutect2, pindel, varscan2
- TAF1 | c.2057G>A p.R686Q (on ENST00000373790 / NM_138923.4; = p.R707Q on NM_004606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 11/273 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV52111050, COSV52128180; called by muse, mutect2
- SRCAP | c.5893_5894insTT p.R1965Lfs*3 | Frame Shift Ins (INS) | VAF 17/97 reads (18%) | called by mutect2, pindel, varscan2
